Surgical pathology report (de-identified scan), TCGA case TCGA-DF-A2KY, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Ontario Institute for Cancer Research, specimen TCGA-DF-A2KY-01A (Primary Tumor).

Sample Type TUMOUR

Sample Preparation

Fresh Frozen

Site of Primary (Event)

Uterine

Site of Tissue

posterior endometrial mass

Year of Sample Collection

Age at Sample Collection (yrs)

105-0-3

Sample Comments

adenocarcinoma, endometrioid, NOS 8380/3

Days to Procedure Date

0

Days to Diagnosis

12

Site: endometrium C54.1

11/4/11

Type of Procedure

Surgical resection

Site of Primary (Histology)

Uterus

Bilateral Disease

UNK

Tumour Size (cm)

5

Histology

Endometrioid adenocarcinoma, NOS & Endometrioid with

squamous differentiation

Grade/Differentiation

III

Pathological T

T4

Pathological N

N1

Number of Nodes Sampled

1

Number of Nodes Positive

12

Clinical M

M0

Histology Comments

Histologic type: Endometrioid adenocarcinoma, poorly differentiated with squamous differentiation. Focal areas of well differentiated endometrioid adenocarcinoma, conventional type. Bladder flap: Metastatic adenocarcinoma of endometrial origin.

Source: NCI Genomic Data Commons file 908bd381-bd24-4d6f-8dd1-7faad9230cea (TCGA-DF-A2KY.8A35F74A-AFA4-4B2D-931B-FA2DE895F010.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).